Somatic mutation profile of tumor specimen TCGA-TQ-A7RP-01A (aliquot TCGA-TQ-A7RP-01A-21D-A34A-08) from TCGA case TCGA-TQ-A7RP, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 66.0 years (24,109 days).
Specimen TCGA-TQ-A7RP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2089229a-ef30-428f-a3dc-18482e4f9e10.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TQ-A7RP-10A (Blood Derived Normal), aliquot TCGA-TQ-A7RP-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/391af852-7cdf-4694-9eab-d1ecdaae809e

The open-access MAF lists 37 somatic variants for this specimen: 29 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 24, Silent 8, Nonsense Mutation 4, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 19/94 reads (20%) | catalogued as rs121909228, CM981674, COSV64288912, COSV64292115, COSV64297607; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SOS1 | c.2536G>A p.E846K | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as rs397517159, CM070272, COSV67673763; ClinVar: pathogenic; called by muse, mutect2
- ADAMTS16 | c.2662+1G>A p.X888_splice | Splice Site (SNP) | VAF 6/42 reads (14%) | catalogued as rs1319370332, COSV56981775, COSV99941605; called by muse, mutect2, varscan2
- C9orf72 | c.502C>T p.Q168* | Nonsense Mutation (SNP) | VAF 8/75 reads (11%) | catalogued as CM162940, COSV101186528; called by muse, mutect2, varscan2
- CACNA2D3 | c.926A>G p.N309S | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.526); catalogued as COSV99874359; called by muse, mutect2
- CD81 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.519); catalogued as COSV99719225; called by muse, mutect2, varscan2
- CEL | c.119A>G p.N40S (on ENST00000673714; = p.N37S on NM_001807.6) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.044); catalogued as rs755568297, COSV60830226; called by muse, mutect2
- CRYGA | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.611); catalogued as rs958131696, COSV100378453; called by muse, mutect2, varscan2
- CYP11A1 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.517); catalogued as rs916391071, COSV99165920; called by muse, mutect2, varscan2
- DEPP1 | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs754189199, COSV100024431; called by muse, mutect2, varscan2
- DNAJC13 | c.3334G>A p.D1112N | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99607469; called by muse, mutect2, varscan2
- FLT1 | c.1033G>T p.E345* | Nonsense Mutation (SNP) | VAF 8/66 reads (12%) | catalogued as COSV56734556, COSV99162987; called by muse, mutect2, varscan2
- GNA14 | c.536G>C p.R179P | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100503114, COSV59027146; called by muse, mutect2, varscan2
- LGALS13 | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as rs534285827, COSV55680035; called by muse, mutect2
- LTBP1 | c.4680G>A p.M1560I (on ENST00000404816 / NM_206943.4; = p.M1234I on NM_000627.4) | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as rs1365127797; called by muse, varscan2
- MISP | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as rs149547647; called by muse, mutect2, varscan2
- MXRA5 | c.2789T>A p.V930D | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99477452; called by muse, mutect2, varscan2
- MYO1G | c.1724C>T p.T575M | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370788368; called by muse, mutect2, varscan2
- NF1 | c.4394A>G p.N1465S (on ENST00000358273 / NM_001042492.3; = p.N1444S on NM_000267.3) | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.194); catalogued as rs786202492, COSV100647367; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR5T3 | c.349G>T p.V117F | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV100282841; called by muse, mutect2
- PHEX | c.626C>A p.S209Y | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.478); catalogued as COSV101039722; called by muse, mutect2, varscan2
- PREX2 | c.919G>A p.V307M | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99907908; called by muse, mutect2
- RRAD | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1420095574, COSV55336293; called by muse, mutect2, varscan2
- RYR2 | c.3314T>C p.F1105S | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV100771023; called by muse, mutect2, varscan2
- SCAF11 | c.2938G>A p.G980R | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV101014417; called by muse, mutect2, varscan2
- SERPINB10 | c.816G>C p.K272N | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.108); catalogued as COSV99449324; called by muse, mutect2
- TMC2 | c.2560C>T p.P854S | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100727244; called by muse, mutect2
- MYCBP2 | c.7372A>G p.K2458E (on ENST00000357337; = p.K2496E on NM_015057.5) | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.79); PolyPhen benign (0.027); called by muse, mutect2
- POLR2A | c.2305A>G p.M769V | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- B4GALT4 | c.828G>A p.R276= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as COSV100785822; called by muse, mutect2, varscan2
- CCSER1 | c.1752C>T p.D584= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as rs559086817, COSV61409183; called by muse, mutect2
- DCAF12L2 | c.1065G>A p.S355= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV100758652; called by muse, mutect2, varscan2
- HS3ST1 | c.414G>A p.P138= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as rs763572146, COSV50023545; called by mutect2, varscan2
- MPIG6B | c.231C>A p.L77= | Silent (SNP) | VAF 6/99 reads (6%) | catalogued as COSV101008115; called by muse, mutect2
- PTPDC1 | c.852C>T p.H284= (on ENST00000375360 / NM_177995.3; = p.H336= on NM_152422.4) | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as rs748008315, COSV99997679; called by muse, mutect2
- SH3TC1 | c.771G>A p.P257= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs899557601, COSV99794965; called by muse, mutect2
- TMUB1 | c.129G>A p.P43= | Silent (SNP) | VAF 21/109 reads (19%) | catalogued as COSV99879809; called by muse, mutect2, varscan2
